Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3587, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3587-01A (Primary Tumor).

Diagnosis:

Rectal resection preparation with tumor-free oral and aboral resection margins and moderately differentiated adenocarcinoma (G2) in the distal rectum with superficial invasion of the lamina muscularis propria and without regional lymph node metastases (pT2 pN0 0/17 L0 V0 R0).

Source: NCI Genomic Data Commons file d2fd89b1-a936-4fdd-8513-29b571f8df10 (TCGA-AG-3587.1FE1F8EC-CAFB-4607-96B9-8597D21D3832.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).